Gene-level copy-number profile of tumor specimen TCGA-EE-A2MG-06A from TCGA case TCGA-EE-A2MG, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 27.9 years (10,198 days).
Specimen TCGA-EE-A2MG-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.00e3b92b-f2a3-494c-b550-e9eafb7d69ee.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EE-A2MG-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1084c0c4-f30e-4a60-bd24-bab63a34465f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 27,712; copy number 2: 31,897; copy number 3: 206; copy number 5: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EE-A2MG-06A-11D-A191-01): tumor purity 0.31, ploidy 1.72, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:24,472,798–24,827,632, 5 genes, copy number 5 (within-gene range 1–5): AC008938.1, RBBP6, TNRC6A, LINC01567, AC008731.1.

Autosomal genes at a single copy (total copy number 1): 25,331. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
